Somatic mutation profile of tumor specimen C3L-02204-01 (aliquot CPT0389370006) from CPTAC case C3L-02204, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Kidney, NOS; Tumor grade: GX; Age at diagnosis: 63.2 years (23,094 days).
Specimen C3L-02204-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 867ea021-1341-4b61-ac3a-eef64c6b63a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02204-31 (Blood Derived Normal), aliquot CPT0389430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1694862-1519-4fd9-9f9a-64440144b348

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNL1 | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 114/265 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs201780688, COSV64835076, COSV64835467; called by muse, mutect2, varscan2
- GOLGA6B | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 115/1527 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.756); catalogued as COSV101406933; called by muse, mutect2
- RASAL2 | c.3262C>T p.R1088W | Missense Mutation (SNP) | VAF 90/135 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761627563; called by muse, mutect2, varscan2
- SLCO4C1 | c.899+2C>T p.X300_splice | Splice Site (SNP) | VAF 22/50 reads (44%) | catalogued as rs1360307731; called by mutect2, varscan2
- AFG3L2 | c.138dup p.A47Sfs*28 | Frame Shift Ins (INS) | VAF 62/200 reads (31%) | called by mutect2, pindel, varscan2
- CCNT2 | c.210G>T p.M70I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CFAP221 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, varscan2
- LAMA5 | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 106/260 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- WDR72 | c.2489T>C p.L830S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2
- INPP5D | c.1308C>T p.D436= (on ENST00000445964 / NM_001017915.3; = p.D435= on NM_005541.5) | Silent (SNP) | VAF 239/701 reads (34%) | catalogued as rs771028425, COSV64037527; called by muse, mutect2, varscan2
- UBL4B | c.99G>A p.R33= | Silent (SNP) | VAF 225/352 reads (64%) | called by muse, mutect2, varscan2
